Somatic mutation profile of tumor specimen TCGA-EJ-7791-01A (aliquot TCGA-EJ-7791-01A-11D-2114-08) from TCGA case TCGA-EJ-7791, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.4 years (24,621 days).
Specimen TCGA-EJ-7791-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a83f522-5a0f-440d-b3b6-2d1aa9696c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7791-10A (Blood Derived Normal), aliquot TCGA-EJ-7791-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e3e5ee1-c63f-4bb4-95c6-8f0932b90542

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 14/116 reads (12%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- B3GALT2 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV66463942; called by muse, mutect2, varscan2
- CD163 | c.1913T>G p.F638C | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63130833; called by muse, mutect2
- DDX31 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV60134972; called by muse, mutect2, varscan2
- KLHL26 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV56316761; called by muse, mutect2
- LTK | c.358C>T p.L120= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV55489912; called by muse, mutect2, varscan2
- NPY2R | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61527720; called by muse, mutect2, varscan2
- RXRG | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63231584; called by muse, mutect2
- TBCCD1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs1211316098, COSV58661801; called by muse, mutect2
- AL136295.1 | c.1704G>A p.V568= | Silent (SNP) | VAF 11/177 reads (6%) | catalogued as COSV55778878; called by muse, mutect2
- HSPD1 | c.1233T>C p.D411= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as COSV61444022; called by muse, mutect2
- SCN10A | c.207G>A p.E69= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as rs1250491105, COSV71860847; called by muse, mutect2
